FM case AD12635 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/2edb5d7e-ea78-43aa-83b0-7a41d2497f8e

Male, 78.9 years: Mesothelioma, NOS (ICD-O-3 9050/3) of the pleura; metastasis biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
